Surgical pathology report (de-identified scan), TCGA case TCGA-G7-A4TM, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-G7-A4TM-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN(S):

A. PARTIAL RIGHT NEPHRECTOMY

CLINICAL HISTORY:

None Given

PRE-OPERATIVE DIAGNOSIS:

None Given

DIAGNOSIS:

A. KIDNEY, RIGHT, PARTIAL NEPHRECTOMY:

- PAPILLARY RENAL CELL CARCINOMA (3.8 X 3.5 X 2.3 CM), TYPE 1

- SURGICAL MARGINS NEGATIVE FOR CARCINOMA

- SEE SYNOPTIC REPORT

SYNOPTIC REPORT - KIDNEY (PARTIAL OR RADICAL)

Specimens Involved

Specimens: A: PARTIAL RIGHT NEPHRECTOMY

Specimen Type: Partial nephrectomy

Without adrenal gland

Laterality: Right

Tumor Site: Not specified

Focality: Unifocal

Tumor Size (largest tumor if multiple): Greatest dimension: 3.8cm

Additional dimensions: 3.5cm x 2.3cm

Macroscopic Extent of Tumor: Tumor limited to kidney

WHO CLASSIFICATION

Papillary renal cell carcinoma 8260/3

ICD-0-3

carcinoma, renal cell 8260/3

Site: Kidney, NOS C64.9

fw
10/10/12

[page 2 of 2]
Histologic Grade (Fuhrman Nuclear Grade): G2: Nuclei slightly irregular, approximately 15 u; nucleoli evident

Invasion of Vascular/Lymphatic: Indeterminate

Perinephric Tissue Invasion: Absent

Margins: Margins uninvolved by invasive carcinoma

Adrenal Gland: Not present

Regional Lymph Nodes: None sampled

Additional Findings: None identified

Pathological Staging (pTNM): pT 1a N X M X

Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition

GROSS DESCRIPTION:

A. PARTIAL RIGHT NEPHRECTOMY

Received fresh labeled with the patient's identification and designated "partial right nephrectomy" is an intact partial nephrectomy specimen weighing 18 g and measuring 3.8 x 3.5 x 2.3 cm. The parenchymal margin previously inked black, remainder of the specimen-blue. The specimen is sectioned to show a soft white/tan focally hemorrhagic mass with lobulated cut surface, 3.3 x 3 x 2.5 cm, located 0.2 cm from the parenchymal margin. Gross photograph is taken. A portion of the specimen is submitted for tissue procurement. Representatively submitted:

A1-A3: Mass, closest parenchymal margin

A4-A8: Additional sections, mass

	Yes	No
Consent		
Identity		
Discrepancy		
History		
Noted		

10/1/12

Source: NCI Genomic Data Commons file c966ab8e-a3b5-41cb-a4c5-a178f80dde77 (TCGA-G7-A4TM.FBF36830-33C4-47CB-ADAB-BAAE334AECBB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).